Somatic mutation profile of tumor specimen TCGA-85-A513-01A (aliquot TCGA-85-A513-01A-12D-A26M-08) from TCGA case TCGA-85-A513, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.1 years (21,967 days).
Specimen TCGA-85-A513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b76a782f-0bb3-4ed2-bb75-6479ade29d16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A513-10A (Blood Derived Normal), aliquot TCGA-85-A513-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bd37ba0-4e69-4f1a-9c0d-9d3c1f76ded6

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP4M1 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100385004; called by muse, mutect2, varscan2
- ARMCX2 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100168203; called by muse, mutect2
- BST2 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs903071133, COSV99392085; called by muse, mutect2
- CFAP43 | c.4246G>C p.E1416Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100829333; called by muse, mutect2
- DZANK1 | c.1522C>A p.P508T (on ENST00000262547 / NM_001099407.1; = p.P315T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99362674; called by muse, mutect2, varscan2
- ECM1 | c.1086G>C p.W362C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100682084; called by muse, mutect2
- GBF1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100890544; called by muse, mutect2
- HEXA | c.325A>C p.T109P | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99173770; called by muse, mutect2
- HGF | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV55952442; called by muse, mutect2, varscan2
- KBTBD7 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.966); catalogued as COSV101068150; called by muse, mutect2, varscan2
- LAMC1 | c.4046C>T p.A1349V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99279902; called by muse, mutect2
- NAV2 | c.533A>C p.K178T | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100586585; called by muse, mutect2
- POM121L12 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs763947253, COSV68693939, COSV68694430; called by mutect2, varscan2
- SLC31A1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100951927; called by muse, mutect2
- ZNF324B | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV100351699; called by muse, mutect2
- DUSP5 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ADH1C | c.939C>T p.R313= | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as COSV101565188; called by muse, mutect2
- KCNRG | c.39G>C p.G13= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV100078444, COSV53951867; called by muse, mutect2
- SPTA1 | c.1674C>T p.D558= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as rs780161347, COSV63750189; called by muse, mutect2, varscan2
- ZFHX4 | c.5760G>A p.L1920= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99264259, COSV99269057; called by muse, mutect2
